Surgical pathology report (de-identified scan), TCGA case TCGA-74-6578, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Swedish Neurosciences, specimen TCGA-74-6578-01A (Primary Tumor).

[page 1 of 2]
Encounter Date: [REDACTED]

Results: PATHOLOGY / NON GYN
CYTOLOGY [REDACTED]

Status: [REDACTED]

TCGA-74-6578

Collection Information

Collection Date [REDACTED]

Collection Time: [REDACTED]

Lab Information

Lab [REDACTED]

Component Results

SURGICAL PATHOLOGY
REPORT

Case Number: [REDACTED]

Procedures/Addenda Present

Collected: [REDACTED]

Received: [REDACTED]

Signed Out: [REDACTED]

Reported: [REDACTED]

CLINICAL INFORMATION:

Neoplasm of unspecified nature of brain.

ICD-9 code: 239.6.

INTRAPROCEDURAL CONSULTATION:

A. Right parietal tumor (frozen section and touch preparation):
Glioblastoma.

GROSS DESCRIPTION:

A. Received fresh, labeled [REDACTED] designated "A. right parietal tumor", is a 5.8 x 4.7 x 2.5 cm aggregate of tan-gray, hemorrhagic and slightly necrotic cortical brain tissue. A representative portion of tissue is frozen and submitted in AFS. Representative sections are submitted in ten cassettes.

B. Received fresh, labeled [REDACTED] designated "B. CUSA contents", is a 4.0 x 2.5 x 2.0 cm aggregate of multiple hemorrhagic soft tan tissue fragments, entirely submitted in four cassettes. [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS:

A. Right parietal tumor, biopsy:

B. CUSA contents:

Glioblastoma, WHO grade IV/IV, with the following features:

-Degree of cellularity: high.

-Microvascular proliferation: present.

-Necrosis: present.

-Mitotic rate: 10 per 10 HPFs.

-Other features: FISH and MGMT studies (PCR and Immunohistochemistry): pending.

Electronically Signed By

PROCEDURES/ADDENDA:

FISH Date Ordered: [REDACTED]

Status: [REDACTED]

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

[page 2 of 2]
Encounter Date: [REDACTED]

Interpretation

A. Brain, right parietal tumor, FISH results:

- Negative for a 1p/19q codeletion.
- Positive for polysomy 1 and 19.
- Positive for polysomy 7/EGFR.
- Positive for monosomy 10/PTEN.

Results-Comments

At the request of [REDACTED], representative sections of the tumor (block A3) were submitted for FISH analysis. The results are consistent with the stated diagnosis. Please see separate report by [REDACTED]

ICC- IMMUNOHISTOCHEMISTRY Date Ordered: [REDACTED] Status: [REDACTED]

Date Complete: [REDACTED] By: [REDACTED]

Date Reported: [REDACTED]

Interpretation

A. RIGHT PARIETAL TUMOR, MGMT IMMUNOHISTOCHEMISTRY RESULTS:

- TUMOR IS POSITIVE FOR MGMT (APPROXIMATELY 50% OF TUMOR).

Results-Comments

A positive internal control is present (endothelial cells).

MGMT by PCR Date Ordered: [REDACTED] Status: [REDACTED]

Date Complete: [REDACTED] By: [REDACTED]

Date Reported: [REDACTED]

Interpretation

A. RIGHT PARIETAL TUMOR, MGMT Methylation Assay

Gene Methylation detected.

Please see full report from [REDACTED] for additional details accession [REDACTED]

Source: NCI Genomic Data Commons file ddb219b3-3a96-4089-83fa-1c34cc604bd5 (TCGA-74-6578.35F9320C-F804-47E5-904F-4D1A87FDDD35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).